TCGA case TCGA-01-0642 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Ovary; Tissue source site: International Genomics Consortium.
https://portal.gdc.cancer.gov/cases/55afc59f-36a7-4da9-9204-8f2e6fac2139

Biospecimens (1 sample)
- Sample TCGA-01-0642-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.4.
